Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1ZU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1ZU-06A (Metastatic).

Prof. Dr.

1CD-0-3

Melanoma, NOS 8720/3

Site: skin, NOS C44.9

for 7/24/11

Patient: Xxxx
geb. *** **

Datum:

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 80 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. There is a high nucleo ratio. Eosinophilic nucleoli are present. The mitotic count is 10 mitoses per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a sheet like growth pattern. Lymphocytic infiltrates compound approx. 3 percent of the tissue cells. The tumor harbours approx. 10 percent of necrotic tissue.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

Dr

COLF Site = skin

Primary Tumor Site Discrepancy not stated on path		☒
Dual/S, nctious Primary Mcted		☒

Source: NCI Genomic Data Commons file f67b562d-07cf-4dc7-9309-d879ba5cf7e4 (TCGA-FS-A1ZU.9FE3EDA1-2FF1-44A4-9619-C403F2A44D73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).